Surgical pathology report (de-identified scan), TCGA case TCGA-D5-6926, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D5-6926-01A (Primary Tumor).

Department of Cancer Pathology

copy No. 5

Date:

Examination: Histopathological examination

Examination No.:

Patient: XXX

PESEL: XXX

Age:

Gender:

Material: **1. Total organ resection – sigmoid colon.**

Unit in charge:

Physician in charge:

Material collected on:

Material received on:

Expected time of examination:

Clinical diagnosis: **Tumour of the sigmoid colon tumour.**

Examination performed on:

Macroscopic description:

A 18 cm length of the large intestine with a piece of mesentery and fat tissue sized 23 x 10.5 x 3 cm. A cauliflower-shaped, partially ulcerous tumour sized 7.5 x 5.5 x 3 cm found in the mucosa sized 4.5 x 4 x 1.3 cm. The lesion surrounds 100% of the intestine circumference and narrows its lumen, is located 4.4 cm from one of the incision lines and 5.9 cm from the other one. The lesion infiltrates macroscopically the whole thickness of the intestine wall and periintestinal tissues.

Microscopic description:

Adenocarcinoma tubulopapillare (G2). Infiltratio carcinomatosa tunicae muscularis propriae et serosae coli et telae adiposae mesenterii pericolicae. Of note is a massive inflammatory invasion, mainly plasmocytic, in the tumour in its surroundings. Intestine ends free of neoplastic lesions.

Minimum side margin is 0.1 cm. Intestine ends free of neoplastic lesions. Metastases carcinomatosae in lymphonodis (No III/XXXIV). Infiltratio carcinomatosa capsulae lymphonodorum et telae adiposae perinodalis.

Histopathological diagnosis:

Adenocarcinoma tubulopapillare coli. Tubulopapillar adenocarcinoma of the colon. Metastases carcinomatosae in lymphonodis. Cancer metastases in the lymph nodes. (No III/XXXIV). (p2, Dukes C, Astler-Coller C2, pT4a, pN1).

Compliance validated by

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file 668c39b3-1a2a-4f84-a07b-2b2a872c72e7 (TCGA-D5-6926.E5257AC1-CDA4-460E-8959-BC4F221E2C6E.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).